Somatic mutation profile of tumor specimen MMRF_1867_1_BM_CD138pos (aliquot MMRF_1867_1_BM_CD138pos_T1_KBS5U_L05785) from MMRF case MMRF_1867, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.6 years (21,416 days).
Specimen MMRF_1867_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69d34e06-8451-4d7e-930d-cf36cd3878fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1867_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1867_1_PB_Whole_C3_KBS5U_L05806; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fb76498-cda8-475a-83ce-ebce2bbbcfc1

The open-access MAF lists 138 somatic variants for this specimen: 53 protein-altering or splice-affecting, 20 silent, 65 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 42, Missense Mutation 39, Silent 20, Intron 14, Nonsense Mutation 6, 5'UTR 4, Splice Site 3, 3'Flank 2, RNA 2, Splice Region 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 41/86 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASB13 | c.466G>T p.V156F | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs765437248, COSV63090953; called by muse, mutect2, varscan2
- DNER | c.1942G>A p.V648M | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141811504; called by muse, mutect2, varscan2
- IGHJ2 | c.11T>C p.F4S | Missense Mutation (SNP) | VAF 21/21 reads (100%) | PolyPhen possibly damaging (0.498); catalogued as rs572863034; called by muse, mutect2, varscan2
- IGHV3-30 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.042); catalogued as rs751340127; called by muse, varscan2
- IGLV1-47 | c.185C>T p.T62M | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs763047752; called by muse, varscan2
- IGLV1-47 | c.320A>T p.Y107F | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as rs760284038; called by muse, varscan2
- IGLV3-1 | c.335G>C p.S112T | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as rs374018767; called by muse, mutect2, varscan2
- IGLV7-46 | c.217A>G p.S73G | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as rs756073973; called by muse, varscan2
- LPA | c.4441G>A p.V1481I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.1); catalogued as rs749421119; called by muse, mutect2, varscan2
- LRP1 | c.9178G>A p.V3060I | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.972); catalogued as rs748466372, COSV54503111; called by muse, mutect2, varscan2
- MYOM1 | c.3341G>A p.R1114H | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs746247312; called by muse, mutect2, varscan2
- NRP2 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.328); catalogued as rs751370729; called by muse, mutect2, varscan2
- PCDHA12 | c.2300C>T p.T767M | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as rs372461540, COSV56496988; called by muse, mutect2, varscan2
- SON | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.093); catalogued as rs201446136; called by muse, mutect2, varscan2
- TENM2 | c.477C>A p.N159K | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.576); catalogued as rs763730897, COSV72862642; called by muse, mutect2, varscan2
- UQCR10 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 48/117 reads (41%) | catalogued as rs377432442, COSV57458710; called by muse, mutect2, varscan2
- ADCY9 | c.1055_1061del p.E352Vfs*27 | Frame Shift Del (DEL) | VAF 53/146 reads (36%) | called by mutect2, pindel, varscan2
- ADGB | c.2852A>G p.E951G | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ASMTL | c.424T>C p.S142P | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- C10orf88 | c.1101T>C p.V367= | Splice Region (SNP) | VAF 63/131 reads (48%) | called by muse, mutect2, varscan2
- CCDC171 | c.2237G>T p.C746F | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- CFAP47 | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CFAP53 | c.35A>T p.E12V | Missense Mutation (SNP) | VAF 102/186 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBXW10 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FIZ1 | c.1385T>C p.L462P | Missense Mutation (SNP) | VAF 53/71 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- GLIS1 | c.898C>T p.Q300* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2, varscan2
- HCRTR2 | c.629G>C p.C210S | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HYDIN | c.12094G>T p.E4032* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | called by muse, mutect2, varscan2
- IGHD | c.409_417del p.R137_E140delinsK | In Frame Del (DEL) | VAF 20/24 reads (83%) | called by mutect2, pindel, varscan2
- IGLV5-45 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.718); called by muse, varscan2
- IGLV5-45 | c.297_300delinsCTAG p.L100* | Nonsense Mutation (ONP) | VAF 5/42 reads (12%) | called by muse*, pindel
- IGLV7-46 | c.230_234del p.S77Yfs*24 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by pindel, varscan2
- IGLV7-46 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- KRTAP9-1 | c.605G>A p.S202N | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT tolerated (0.46); called by muse, mutect2, varscan2
- LRRC10B | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- MARCHF10 | c.169T>A p.F57I | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MMP14 | c.796A>G p.T266A | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NOS3 | c.919C>A p.P307T | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- OTOGL | c.3797T>G p.V1266G (on ENST00000547103; = p.V1257G on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- PEAR1 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- PNPLA8 | c.1841A>G p.Y614C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTK2 | c.2230-2A>G p.X744_splice | Splice Site (SNP) | VAF 38/87 reads (44%) | called by muse, mutect2, varscan2
- RAB8A | c.246+2T>C p.X82_splice | Splice Site (SNP) | VAF 43/69 reads (62%) | called by muse, mutect2, varscan2
- RELL1 | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- RNF128 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ROBO2 | c.4136-1G>A p.X1379_splice | Splice Site (SNP) | VAF 86/247 reads (35%) | called by muse, mutect2, varscan2
- SH3BGRL2 | c.315A>T p.A105= | Splice Region (SNP) | VAF 49/111 reads (44%) | called by muse, mutect2, varscan2
- SLC22A10 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.699); called by muse, mutect2
- STARD7 | c.79T>C p.C27R | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- WDR64 | c.1904C>A p.S635Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- XPO4 | c.2899T>A p.S967T | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF652 | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 63/115 reads (55%) | called by muse, mutect2, varscan2
- ACTG1 | c.90G>A p.V30= | Silent (SNP) | VAF 71/163 reads (44%) | catalogued as rs782399347; called by muse, mutect2, varscan2
- BDH1 | c.420C>T p.G140= | Silent (SNP) | VAF 20/90 reads (22%) | called by muse, mutect2, varscan2
- C1QTNF4 | c.273G>A p.S91= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs1439175430; called by muse, mutect2, varscan2
- CCDC148 | c.612T>G p.T204= | Silent (SNP) | VAF 25/69 reads (36%) | called by muse, mutect2, varscan2
- CDC14C | c.444A>G p.V148= (on ENST00000428251; = p.V41= on NM_152627.3) | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs764155789; called by muse, mutect2, varscan2
- CNTLN | c.2283A>G p.Q761= | Silent (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- DNAH9 | c.12543G>A p.P4181= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as rs571913392, COSV52346856; called by muse, mutect2, varscan2
- DTNA | c.1654C>T p.L552= | Silent (SNP) | VAF 40/71 reads (56%) | called by muse, mutect2, varscan2
- FAM126A | c.690A>C p.I230= | Silent (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- FOXE1 | c.858C>T p.G286= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs770871331; called by muse, varscan2
- IGHV2-70 | c.132T>C p.S44= | Silent (SNP) | VAF 46/80 reads (58%) | catalogued as rs372598742; called by muse, varscan2
- IGHV2-70 | c.129C>T p.F43= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as rs548066677; called by muse, varscan2
- JAK3 | c.3330C>T p.F1110= | Silent (SNP) | VAF 155/224 reads (69%) | catalogued as COSV101512893; called by muse, mutect2, varscan2
- MBD5 | c.2382G>A p.G794= | Silent (SNP) | VAF 75/154 reads (49%) | called by muse, mutect2, varscan2
- MORC1 | c.597T>C p.V199= | Silent (SNP) | VAF 86/140 reads (61%) | called by muse, mutect2, varscan2
- NKD2 | c.1086G>A p.P362= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs567751276; called by muse, mutect2, varscan2
- PDLIM2 | c.1029C>T p.S343= (on ENST00000397760; = p.S593= on NM_021630.6) | Silent (SNP) | VAF 52/61 reads (85%) | catalogued as rs753951550; called by muse, mutect2, varscan2
- RPIA | c.141A>G p.A47= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs1376613424; called by muse, mutect2, varscan2
- ZFHX3 | c.7914T>A p.P2638= | Silent (SNP) | VAF 45/108 reads (42%) | called by muse, mutect2, varscan2
- ZNF425 | c.126C>T p.Y42= | Silent (SNP) | VAF 88/155 reads (57%) | catalogued as rs770848398, COSV65200912; called by muse, mutect2, varscan2
- ACTRT1 | c.*106C>G | 3'UTR (SNP) | VAF 80/250 reads (32%) | called by muse, mutect2, varscan2
- ANGPTL3 | c.*282T>C | 3'UTR (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- ANKRD36B | c.-39A>G | 5'UTR (SNP) | VAF 52/102 reads (51%) | catalogued as rs766294687; called by muse, mutect2, varscan2
- ARSK | c.126+1315dup | Intron (INS) | VAF 12/27 reads (44%) | called by mutect2, pindel, varscan2
- ATP6V0E2 | c.*95A>G | 3'UTR (SNP) | VAF 21/126 reads (17%) | catalogued as rs749176357; called by muse, mutect2, varscan2
- BTBD3 | c.*876C>T | 3'UTR (SNP) | VAF 48/108 reads (44%) | called by muse, mutect2, varscan2
- C1orf159 | c.73-163C>T | Intron (SNP) | VAF 7/17 reads (41%) | catalogued as rs183940959; called by muse, mutect2, varscan2
- CDH20 | c.*38G>T | 3'UTR (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- CNPY4 | c.*377C>G | 3'UTR (SNP) | VAF 38/62 reads (61%) | called by muse, mutect2, varscan2
- CSRNP3 | c.*8751T>A | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- CTSS | c.*940G>A | 3'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- DCAF4L2 | c.*465T>A | 3'UTR (SNP) | VAF 66/128 reads (52%) | called by muse, mutect2, varscan2
- DPP6 | c.-416G>A | 5'UTR (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- DTNA | c.1662+2093G>T | Intron (SNP) | VAF 11/250 reads (4%) | called by muse, mutect2
- E2F7 | c.*1699dup | 3'UTR (INS) | VAF 10/19 reads (53%) | called by mutect2, pindel, varscan2
- ECE1 | c.*354del | 3'UTR (DEL) | VAF 39/87 reads (45%) | called by mutect2, pindel, varscan2
- EDEM1 | c.*417G>A | 3'UTR (SNP) | VAF 18/27 reads (67%) | catalogued as rs1377562863; called by muse, mutect2, varscan2
- EML1 | c.*127C>T | 3'UTR (SNP) | VAF 32/72 reads (44%) | catalogued as rs1420220226; called by muse, mutect2, varscan2
- EML2 | c.1122+21C>T | Intron (SNP) | VAF 25/71 reads (35%) | catalogued as rs1383929504; called by muse, mutect2, varscan2
- EPHA7 | c.*306G>C | 3'UTR (SNP) | VAF 23/41 reads (56%) | called by muse, mutect2, varscan2
- FAM3A | c.335-14C>T | Intron (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- FEZF2 | c.*113C>T | 3'UTR (SNP) | VAF 35/97 reads (36%) | catalogued as COSV99334572; called by muse, mutect2, varscan2
- FOXF1 | c.*708C>T | 3'UTR (SNP) | VAF 61/131 reads (47%) | called by muse, mutect2, varscan2
- GNE | c.*1135T>A | 3'UTR (SNP) | VAF 63/213 reads (30%) | catalogued as rs753879971; called by muse, mutect2, varscan2
- GRIA3 | c.508+140G>T | Intron (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- HPS5 | c.1510+14C>G | Intron (SNP) | VAF 13/226 reads (6%) | called by muse, mutect2
- IFNW1 | c.-291C>T | 5'UTR (SNP) | VAF 34/46 reads (74%) | catalogued as rs940788734; called by muse, mutect2, varscan2
- LIMK2 | c.1773-962G>A | Intron (SNP) | VAF 27/53 reads (51%) | called by muse, mutect2, varscan2
- LINC01547 | n.3993C>A | RNA (SNP) | VAF 81/221 reads (37%) | called by muse, mutect2, varscan2
- LTB | c.162+78T>G | Intron (SNP) | VAF 30/55 reads (55%) | called by muse, mutect2, varscan2
- MIR1305 | n.25G>A | RNA (SNP) | VAF 29/64 reads (45%) | catalogued as rs372725675; called by muse, mutect2, varscan2
- MLEC | c.*1008G>T | 3'UTR (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- MYLK | c.*165A>T | 3'UTR (SNP) | VAF 65/118 reads (55%) | called by muse, mutect2, varscan2
- MYLK | c.*27A>G | 3'UTR (SNP) | VAF 111/185 reads (60%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*4417del | 3'UTR (DEL) | VAF 109/174 reads (63%) | catalogued as rs113411923; called by mutect2, varscan2
- PCBP2 | c.838+192A>C | Intron (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2
- PDPN | c.*502C>A | 3'UTR (SNP) | VAF 33/57 reads (58%) | called by muse, mutect2, varscan2
- PINLYP | c.482-19T>C | Intron (SNP) | VAF 36/93 reads (39%) | called by muse, mutect2, varscan2
- PIP5KL1 | c.434+26G>A | Intron (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- POLR2K | c.*675T>G | 3'UTR (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- PRKD1 | c.*224G>A | 3'UTR (SNP) | VAF 45/83 reads (54%) | called by muse, mutect2, varscan2
- RAB11FIP2 | c.*3718A>T | 3'UTR (SNP) | VAF 34/67 reads (51%) | called by muse, mutect2, varscan2
- RAD52 | c.*719C>T | 3'UTR (SNP) | VAF 8/13 reads (62%) | called by muse, mutect2, varscan2
- RASSF3 | c.*169C>A | 3'UTR (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- RBM17 | c.*1315T>C | 3'UTR (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- RBM3 | c.210+213C>T | Intron (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- RMI1 | c.*733dup | 3'UTR (INS) | VAF 16/33 reads (48%) | called by mutect2, varscan2
- RNF128 | c.*1060A>G | 3'UTR (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- SEPTIN14 | c.*199G>T | 3'UTR (SNP) | VAF 26/58 reads (45%) | catalogued as COSV66430696; called by mutect2, varscan2
- SLC22A23 | c.*426C>T | 3'UTR (SNP) | VAF 35/81 reads (43%) | catalogued as rs1036271689; called by muse, mutect2, varscan2
- SLC2A5 | c.*386A>G | 3'UTR (SNP) | VAF 34/62 reads (55%) | called by muse, varscan2
- SLC2A5 | c.*306A>G | 3'UTR (SNP) | VAF 34/72 reads (47%) | called by muse, varscan2
- SLC2A5 | c.*231T>G | 3'UTR (SNP) | VAF 45/76 reads (59%) | called by muse, varscan2
- SLC2A5 | c.*151A>T | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- SLC35E3 | c.*1191A>C | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- SPANXN2 | c.-34G>T | 5'UTR (SNP) | VAF 21/324 reads (6%) | catalogued as COSV100979902; called by muse, mutect2
- SPRY3 | c.*4742dup | 3'UTR (INS) | VAF 73/264 reads (28%) | called by mutect2, pindel, varscan2
- SUSD4 | c.*924C>A | 3'UTR (SNP) | VAF 34/66 reads (52%) | called by muse, mutect2, varscan2
- TBX4 | c.*90G>T | 3'UTR (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- TET2 | c.3500+521_3500+525del | Intron (DEL) | VAF 3/27 reads (11%) | catalogued as rs1222372042; called by pindel, varscan2*
- TMEM33 | chr4:41960473 T>C | 3'Flank (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975387 T>C | 5'Flank (SNP) | VAF 46/96 reads (48%) | called by muse, mutect2
- TSC22D3 | c.*1205C>T | 3'UTR (SNP) | VAF 34/122 reads (28%) | called by muse, mutect2, varscan2
- Z82198.2 | chr22:33166734 C>T | 3'Flank (SNP) | VAF 145/258 reads (56%) | called by muse, mutect2, varscan2
- ZNF500 | c.*3138C>T | 3'UTR (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
